Somatic mutation profile of tumor specimen 0DA4KF from CCDI case PBBJNF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.6 years (1,684 days).
Specimen 0DA4KF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19cc92b4-bfe3-462b-b9e6-d154e38a94b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA4I8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2c21a86-f4da-461e-91c4-23ecfc42efdb

The open-access MAF lists 60 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Intron 7, 5'UTR 2, 3'UTR 2, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A6 | c.1961T>C p.I654T | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1310926114, COSV62028707; called by muse, mutect2, varscan2
- DOCK5 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 81/441 reads (18%) | catalogued as rs778453756; called by muse, mutect2, varscan2
- H4C11 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.954); catalogued as rs758581420, COSV100747976; called by muse, mutect2, varscan2
- NLRP1 | c.32G>C p.C11S | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1317931422; called by muse, mutect2, varscan2
- NLRP8 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs374619959; called by muse, mutect2, varscan2
- NME8 | c.931A>G p.K311E | Missense Mutation (SNP) | VAF 24/625 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.269); catalogued as rs1246792641; called by muse, mutect2
- NUP153 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.238); catalogued as rs543593216, COSV50451937; called by muse, mutect2, varscan2
- PEG3 | c.1266G>T p.M422I | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV55640645; called by muse, mutect2, varscan2
- RNF213 | c.6869C>T p.A2290V | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.524); catalogued as rs766053171, COSV60392616; called by muse, mutect2, varscan2
- SCNN1B | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56301112; called by muse, mutect2, varscan2
- TIE1 | c.3325C>T p.R1109C | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs6698998; called by muse, mutect2, varscan2
- TNRC18 | c.2368C>A p.R790S | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs902811044, COSV68164285; called by muse, varscan2
- A2M | c.1538T>G p.L513R | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- A4GNT | c.359A>T p.D120V | Missense Mutation (SNP) | VAF 74/402 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ACTN2 | c.2152G>C p.E718Q | Missense Mutation (SNP) | VAF 95/435 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ADAMTS1 | c.1585dup p.A529Gfs*27 | Frame Shift Ins (INS) | VAF 60/258 reads (23%) | called by mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CBX4 | c.1280G>C p.R427P | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.774); called by muse, varscan2
- DAGLA | c.2905G>T p.V969L | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- FAM155A | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 19/575 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.716); called by muse, mutect2
- FANCA | c.3137A>C p.H1046P | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- FARSB | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- FLNB | c.5323G>C p.E1775Q | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- GBP1 | c.53A>G p.N18S | Missense Mutation (SNP) | VAF 53/374 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPR82 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 93/117 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAS3 | c.1183G>C p.A395P | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- HMCN2 | c.4154T>C p.I1385T | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- HOXB1 | c.331T>A p.F111I | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2B | c.7872+2T>A p.X2624_splice | Splice Site (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- METTL18 | c.452T>C p.F151S | Missense Mutation (SNP) | VAF 68/487 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OSBP2 | c.2376-1G>C p.X792_splice | Splice Site (SNP) | VAF 28/138 reads (20%) | called by muse, varscan2
- PHF20 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 85/266 reads (32%) | called by muse, mutect2, varscan2
- PIANP | c.827+5G>C | Splice Region (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- PKP1 | c.1367C>A p.A456D | Missense Mutation (SNP) | VAF 20/594 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.201); called by muse, mutect2
- SOX1 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, varscan2
- SPAG9 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 67/485 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.545); called by muse, mutect2
- SYNE1 | c.25831T>C p.S8611P (on ENST00000367255 / NM_182961.4; = p.S8563P on NM_033071.3) | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- TRIM5 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF419 | c.1476dup p.R493Sfs*8 | Frame Shift Ins (INS) | VAF 39/288 reads (14%) | called by mutect2, varscan2
- CELSR3 | c.4176C>T p.S1392= | Silent (SNP) | VAF 62/216 reads (29%) | catalogued as rs1164959849; called by muse, mutect2, varscan2
- DMC1 | c.447T>A p.G149= | Silent (SNP) | VAF 39/229 reads (17%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2295T>G p.S765= | Silent (SNP) | VAF 49/242 reads (20%) | called by muse, mutect2, varscan2
- GATA5 | c.1152G>A p.G384= | Silent (SNP) | VAF 52/195 reads (27%) | called by muse, mutect2, varscan2
- MYO16 | c.1456C>A p.R486= | Silent (SNP) | VAF 61/317 reads (19%) | catalogued as COSV51777831; called by muse, mutect2, varscan2
- RBBP6 | c.2211C>T p.G737= | Silent (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- RESF1 | c.3759C>T p.D1253= | Silent (SNP) | VAF 55/261 reads (21%) | catalogued as rs150095870; called by muse, mutect2, varscan2
- RP1 | c.1114A>C p.R372= | Silent (SNP) | VAF 151/369 reads (41%) | called by muse, mutect2, varscan2
- SLC17A3 | c.432C>T p.G144= | Silent (SNP) | VAF 36/222 reads (16%) | called by muse, mutect2, varscan2
- ZNF816 | c.639T>C p.H213= | Silent (SNP) | VAF 42/297 reads (14%) | catalogued as rs141761875; called by muse, mutect2, varscan2
- C15orf61 | c.346+21C>T | Intron (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- C22orf42 | c.493+16del | Intron (DEL) | VAF 96/306 reads (31%) | catalogued as rs745800176, COSV66075696; called by mutect2, varscan2
- C5orf58 | c.-84-48G>A | Intron (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- ELL2 | c.481+61G>C | Intron (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- ESRP1 | c.133-47G>A | Intron (SNP) | VAF 19/140 reads (14%) | called by mutect2, varscan2
- GFUS | c.465-40C>T | Intron (SNP) | VAF 9/35 reads (26%) | catalogued as rs765215066; called by muse, mutect2, varscan2
- LCE1E | c.-6G>A | 5'UTR (SNP) | VAF 31/233 reads (13%) | called by mutect2, varscan2
- MFSD12 | c.*1C>A | 3'UTR (SNP) | VAF 26/222 reads (12%) | catalogued as rs1353802333; called by muse, mutect2
- MMP19 | c.521-38C>G | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 7/62 reads (11%) | called by muse, varscan2
- WDR36 | c.*41G>A | 3'UTR (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
